EXCEPTIONAL_RESPONDERS case ER-B1I5 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Other and unspecified female genital organs. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/08811ee6-60fc-4097-9207-4b03e9f92bd4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1941; Vital status: Alive.

Diagnoses (1)
1. Serous carcinoma, NOS: ICD-O-3 morphology code: 8441/3; Tissue or organ of origin: Fallopian tube; Site of resection or biopsy: Fallopian tube; Classification of tumor: primary; Age at diagnosis: 66.1 years (24,155 days); Year of diagnosis: 2007; AJCC pathologic stage: Stage IIC; Prior malignancy: no; Days to last follow up: 3,694 days (10.1 years); Days to best overall response: 1,392 days (3.8 years); Best overall response: Complete Response.
   Treatment given: Therapeutic agents: Carboplatin + Paclitaxel; Days to treatment start: 1,287 days (3.5 years); Days to treatment end: 1,392 days (3.8 years).

Follow-up (1 entry)
- Days to follow up: 3,694 days (10.1 years); Disease response: Stable Disease; Progression or recurrence: Yes; Days to recurrence: 1,238 days (3.4 years); Days progression-free: 3,694 days (10.1 years).

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B1I5-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B1I5-TTM1-A-1-0-S1: Section location: Top; Percent tumor cells: 70; Percent tumor nuclei: 80; Percent normal cells: 10; Percent necrosis: 15; Percent stromal cells: 5; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample ER-B1I5-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
